Gene-level copy-number profile of tumor specimen TCGA-HU-A4G9-01A from TCGA case TCGA-HU-A4G9, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 67.8 years (24,753 days).
Specimen TCGA-HU-A4G9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.218edbca-aaba-4465-abe3-5f2ce7720e8c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HU-A4G9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5200051b-4703-40bf-ab42-0573651eece3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3; copy number 2: 51,739; copy number 3: 5,597; copy number 4: 2,481.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HU-A4G9-01A-11D-A24C-01): tumor purity 0.87, ploidy 2.22, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
